Somatic mutation profile of tumor specimen MMRF_1538_1_BM_CD138pos (aliquot MMRF_1538_1_BM_CD138pos_T1_KBS5U_L03000) from MMRF case MMRF_1538, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.6 years (24,342 days).
Specimen MMRF_1538_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5645360-6997-4ac9-bb71-a6563371149a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1538_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1538_1_PB_Whole_C3_KBS5U_L03008; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80b25d37-eda1-4996-b19d-cfc5e02867f1

The open-access MAF lists 77 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 27, Missense Mutation 23, Intron 9, Silent 7, Frame Shift Del 5, Nonsense Mutation 3, RNA 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 34/77 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACE | c.1011del p.M338Cfs*118 | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | catalogued as rs1196439789; called by mutect2, pindel, varscan2
- ANKRD2 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs780214039, COSV53967739; called by muse, mutect2, varscan2
- CFAP100 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1019765015; called by muse, mutect2, varscan2
- CPEB2 | c.249del p.S84Pfs*18 | Frame Shift Del (DEL) | VAF 80/214 reads (37%) | catalogued as rs1202244406; called by mutect2, pindel, varscan2
- ELL2 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV99427693; called by muse, mutect2
- FHAD1 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as rs1206275776; called by muse, mutect2, varscan2
- IGHV2-70 | c.262del p.L88Sfs*16 | Frame Shift Del (DEL) | VAF 39/109 reads (36%) | catalogued as rs753140439; called by pindel, varscan2
- IL20 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768935657; called by muse, mutect2, varscan2
- IMPDH1 | c.437C>T p.T146M (on ENST00000470772 / NM_001142573.2; = p.T232M on NM_000883.4) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as rs145251520; called by muse, mutect2, varscan2
- LONRF2 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs1234089537; called by muse, mutect2
- MATN4 | c.1270C>T p.R424W (on ENST00000372754; = p.R383W on NM_003833.4) | Missense Mutation (SNP) | VAF 85/201 reads (42%) | PolyPhen probably damaging (0.992); catalogued as rs747225057, COSV61350549; called by muse, mutect2, varscan2
- PTPRB | c.4987C>G p.R1663G | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV54251658; called by muse, mutect2, varscan2
- SLC12A8 | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.759); catalogued as COSV100103318; called by muse, mutect2, varscan2
- SUPT6H | c.4934A>G p.Q1645R | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs745370263; called by muse, mutect2, varscan2
- TET1 | c.6070C>T p.R2024W | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1222112424, COSV65388797; called by muse, mutect2, varscan2
- THY1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201203569, COSV52453887; called by muse, mutect2, varscan2
- TMPRSS11D | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs769440865, COSV52222471; called by muse, mutect2, varscan2
- ZNF282 | c.1295C>G p.P432R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as rs1347116510; called by muse, mutect2, varscan2
- BACH1 | c.1906C>T p.Q636* | Nonsense Mutation (SNP) | VAF 44/89 reads (49%) | called by muse, mutect2, varscan2
- CCDC62 | c.1523G>A p.S508N | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL24A1 | c.3262A>G p.I1088V | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EDNRB | c.1534A>C p.K512Q (on ENST00000377211 / NM_001201397.1; = p.K422Q on NM_000115.5) | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- MMS22L | c.3426A>C p.K1142N | Missense Mutation (SNP) | VAF 74/116 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MPDZ | c.952G>C p.V318L | Missense Mutation (SNP) | VAF 83/298 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPL42 | c.87T>G p.C29W | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- MUC2 | c.1695C>G p.D565E | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by mutect2, varscan2
- PI4K2A | c.417C>A p.F139L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- SIRT6 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | called by muse, varscan2
- SORT1 | c.2310del p.V771Sfs*2 | Frame Shift Del (DEL) | VAF 57/156 reads (37%) | called by mutect2, pindel, varscan2
- TENM1 | c.5889_5907delinsAC p.T1964Lfs*11 | Frame Shift Del (DEL) | VAF 34/36 reads (94%) | called by pindel, varscan2*
- ACTL9 | c.600C>T p.H200= | Silent (SNP) | VAF 40/196 reads (20%) | catalogued as COSV61004826; called by muse, mutect2, varscan2
- FNDC1 | c.2265C>T p.S755= | Silent (SNP) | VAF 120/455 reads (26%) | called by muse, mutect2, varscan2
- H2BC7 | c.309G>C p.L103= | Silent (SNP) | VAF 62/219 reads (28%) | catalogued as COSV61911656; called by muse, mutect2, varscan2
- NPHP4 | c.2937C>T p.H979= | Silent (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- PCDHA12 | c.798T>A p.A266= | Silent (SNP) | VAF 128/203 reads (63%) | called by muse, mutect2, varscan2
- RPL36A | c.216C>T p.C72= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as rs781827069; called by muse, mutect2
- SLC8A2 | c.906C>G p.P302= | Silent (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- AC098650.1 | c.*115+16920C>G | Intron (SNP) | VAF 28/107 reads (26%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.*298C>T | 3'UTR (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- AGTR2 | c.*936del | 3'UTR (DEL) | VAF 36/39 reads (92%) | catalogued as rs1305444640; called by mutect2, varscan2
- BMP6 | c.*1289G>A | 3'UTR (SNP) | VAF 48/163 reads (29%) | called by muse, mutect2, varscan2
- CALD1 | c.*1384T>C | 3'UTR (SNP) | VAF 86/136 reads (63%) | called by muse, mutect2, varscan2
- CLSTN2 | c.*1807T>A | 3'UTR (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- CUX2 | c.*1814A>T | 3'UTR (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- CYP2E1 | c.*28G>A | 3'UTR (SNP) | VAF 24/58 reads (41%) | catalogued as rs770971237, COSV99429218; called by muse, mutect2, varscan2
- DDX20 | c.1021+310G>T | Intron (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- DPYS | c.*14+78A>T | Intron (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- EDIL3 | c.*1649T>C | 3'UTR (SNP) | VAF 50/151 reads (33%) | called by muse, mutect2, varscan2
- FRMD6 | c.*1968A>G | 3'UTR (SNP) | VAF 16/33 reads (48%) | catalogued as rs902878675; called by muse, mutect2, varscan2
- GK5 | c.*1760G>T | 3'UTR (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- GPR68 | c.*182G>A | 3'UTR (SNP) | VAF 27/98 reads (28%) | catalogued as rs992626303; called by muse, mutect2, varscan2
- ISM1 | c.*843A>C | 3'UTR (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- KCTD17 | c.*426_*436delinsTC | 3'UTR (DEL) | VAF 32/76 reads (42%) | called by pindel, varscan2*
- LBR | c.*616G>A | 3'UTR (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- MEGF9 | c.*2698C>G | 3'UTR (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- MIR30A | n.21C>T | RNA (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- MIR4483 | chr10:113782838 T>C | 5'Flank (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- NUDT12 | c.*759A>C | 3'UTR (SNP) | VAF 50/127 reads (39%) | called by muse, mutect2, varscan2
- NXF3 | c.891-30C>T | Intron (SNP) | VAF 25/25 reads (100%) | called by muse, mutect2, varscan2
- PDE1C | c.1892-13523A>G | Intron (SNP) | VAF 34/50 reads (68%) | called by muse, mutect2, varscan2
- PKHD1 | c.*1651T>G | 3'UTR (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
- PML | c.*1650G>C | 3'UTR (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- PRDM11 | c.657-5913T>C | Intron (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- PRKCB | c.1864-4958C>T | Intron (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- RBM18 | c.*2382G>A | 3'UTR (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- RBM6 | c.-67+315C>T | Intron (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- RBPJ | c.*2280G>A | 3'UTR (SNP) | VAF 16/46 reads (35%) | catalogued as rs976496968; called by muse, mutect2, varscan2
- RSPH3 | chr6:158976207 A>C | 3'Flank (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
- SCEL | c.*634T>G | 3'UTR (SNP) | VAF 41/78 reads (53%) | called by muse, mutect2, varscan2
- SENP1 | c.*1675C>G | 3'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- STIMATE | c.*615C>T | 3'UTR (SNP) | VAF 33/152 reads (22%) | called by muse, mutect2, varscan2
- SUSD4 | c.*519C>T | 3'UTR (SNP) | VAF 23/65 reads (35%) | catalogued as rs1002688329; called by muse, mutect2, varscan2
- SYT4 | c.*162T>C | 3'UTR (SNP) | VAF 55/102 reads (54%) | called by muse, mutect2, varscan2
- UNC45A | c.52-28G>T | Intron (SNP) | VAF 51/164 reads (31%) | catalogued as rs1303233141; called by muse, mutect2, varscan2
- ZNF135 | c.*326C>G | 3'UTR (SNP) | VAF 39/189 reads (21%) | called by muse, mutect2, varscan2
- ZNF778 | c.*5264G>T | 3'UTR (SNP) | VAF 58/155 reads (37%) | called by muse, mutect2, varscan2
